Somatic mutation profile of tumor specimen TCGA-95-7039-01A (aliquot TCGA-95-7039-01A-11D-1945-08) from TCGA case TCGA-95-7039, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.7 years (19,981 days).
Specimen TCGA-95-7039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54cf6411-680d-4de6-b98e-46b9021ace6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7039-10A (Blood Derived Normal), aliquot TCGA-95-7039-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178421c1-a911-4404-81ce-83f399e6e4f8

The open-access MAF lists 1,351 somatic variants for this specimen: 1,028 protein-altering or splice-affecting, 293 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 873, Silent 293, Nonsense Mutation 71, Frame Shift Del 40, Splice Site 22, Frame Shift Ins 16, RNA 15, Intron 10, Splice Region 5, 3'UTR 2, 3'Flank 2, 5'Flank 1.

Variants (750 of 1,351; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.670C>T p.R224* (on ENST00000281708 / NM_001349798.2; = p.R144* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | hotspot (GDC flag); catalogued as rs1406877044, COSV55899023; called by muse, mutect2, varscan2
- KDM5C | c.807del p.T270Qfs*2 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs1569278313; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV55525725, COSV55810858; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 17/25 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV50310075; called by muse, mutect2
- ABCA12 | c.5546G>A p.C1849Y (on ENST00000272895 / NM_173076.3; = p.C1531Y on NM_015657.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55979406; called by muse, mutect2, varscan2
- ABCA2 | c.2945G>T p.W982L (on ENST00000614293; = p.W952L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV55807668; called by muse, mutect2, varscan2
- ABCA7 | c.1023C>G p.D341E | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV54038625; called by muse, mutect2, varscan2
- ABCA8 | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs1315241407, COSV52200855, COSV99286909; called by muse, mutect2
- ABCB4 | c.3217T>C p.C1073R | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55943033; called by muse, mutect2, varscan2
- ABCC4 | c.3366G>T p.Q1122H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65319551; called by muse, mutect2, varscan2
- AC011455.2 | c.1341G>T p.E447D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as rs754330537, COSV55502164; called by muse, mutect2, varscan2
- AC134980.2 | c.693A>T p.E231D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV60909654; called by muse, mutect2
- ACKR2 | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1378432270, COSV56180794; called by muse, mutect2, varscan2
- ACKR3 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745666707, COSV56020972; called by muse, mutect2, varscan2
- ACSM2A | c.1217C>A p.T406K (on ENST00000219054; = p.T327K on NM_001308169.2) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54590826; called by muse, mutect2, varscan2
- ACSM5 | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59375487; called by muse, mutect2, varscan2
- ADAM22 | c.440C>G p.S147* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV55992647; called by muse, mutect2
- ADAM32 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65954093, COSV65954229; called by muse, mutect2, varscan2
- ADAMTS12 | c.2316T>A p.F772L | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61283339; called by muse, mutect2
- ADAMTS14 | c.893A>T p.E298V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV64607331; called by muse, mutect2, varscan2
- ADAMTS16 | c.2902A>G p.S968G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as COSV57009697; called by muse, mutect2
- ADAMTS17 | c.2885G>A p.R962K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV51496093; called by muse, mutect2, varscan2
- ADAMTS2 | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51114912; called by muse, mutect2, varscan2
- ADAMTS20 | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV67141103; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3340G>C p.D1114H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54473649; called by muse, mutect2, varscan2
- ADCY2 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs765899703, COSV57905182; called by muse, mutect2, varscan2
- ADGRE2 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1045143210, COSV100216606; called by muse, mutect2
- ADGRF2 | c.1419C>A p.S473R (on ENST00000296862 / NM_001368115.2; = p.S405R on NM_153839.7) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV57292741; called by muse, mutect2
- ADGRG4 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV54969291; called by muse, mutect2, varscan2
- ADGRG5 | c.556A>T p.T186S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV61084890; called by muse, mutect2, varscan2
- ADGRG6 | c.3259G>T p.A1087S | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51602588; called by muse, mutect2, varscan2
- ADGRL1 | c.3141A>T p.K1047N (on ENST00000340736 / NM_001008701.3; = p.K1042N on NM_014921.5) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV61567065; called by muse, mutect2, varscan2
- ADGRL4 | c.1575C>A p.N525K | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV66066915; called by muse, mutect2, varscan2
- ADGRV1 | c.2206G>T p.E736* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV101316679; called by muse, mutect2, varscan2
- ADH1A | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV52926429; called by muse, mutect2, varscan2
- ADSS1 | c.443A>T p.Q148L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV58276746; called by muse, mutect2, varscan2
- ADTRP | c.602A>T p.Y201F | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57646410; called by muse, mutect2, varscan2
- AEBP1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56256987; called by muse, mutect2
- AGPAT4 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs748012441, COSV57252259; called by muse, mutect2, varscan2
- AGPS | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.431); catalogued as COSV51569983; called by muse, mutect2
- AGRN | c.3250G>T p.G1084W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1377789253, COSV65072815; called by muse, mutect2, varscan2
- AHCTF1 | c.4022G>T p.G1341V (on ENST00000366508; = p.G1315V on NM_015446.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV58256932; called by muse, mutect2, varscan2
- AHCTF1 | c.1276G>T p.G426* (on ENST00000366508; = p.G400* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV58256959; called by muse, mutect2, varscan2
- AHNAK2 | c.12352G>A p.D4118N | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV60933710; called by muse, mutect2, varscan2
- AIRE | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV52397848; called by mutect2, varscan2
- AK8 | c.302C>G p.T101S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV53762117; called by muse, mutect2, varscan2
- AKAP6 | c.4634A>G p.N1545S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55236759; called by muse, mutect2, varscan2
- AKAP6 | c.5065A>T p.T1689S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55236772, COSV99799066; called by muse, mutect2, varscan2
- AKAP9 | c.1933G>T p.E645* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV62359568; called by muse, mutect2, varscan2
- ALAS2 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV100238728; called by muse, varscan2
- ALDH3B1 | c.956C>A p.T319K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50292085; called by muse, mutect2, varscan2
- ALDH8A1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55644811; called by muse, mutect2, varscan2
- ALOX12 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs553679162, COSV99278587; called by muse, mutect2, varscan2
- ALOX5 | c.1925T>G p.L642R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65555039; called by muse, mutect2, varscan2
- AMIGO2 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56975856; called by muse, mutect2, varscan2
- ANK2 | c.64A>G p.R22G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52193567; called by muse, mutect2, varscan2
- ANK2 | c.5714C>A p.S1905* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV52193578; called by muse, mutect2, varscan2
- ANK2 | c.6839C>A p.P2280H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.494); catalogued as COSV52193588; called by muse, mutect2, varscan2
- ANK3 | c.6107A>T p.Y2036F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.158); catalogued as COSV55086389; called by muse, mutect2, varscan2
- ANK3 | c.3721A>G p.N1241D (on ENST00000280772 / NM_001320874.2; = p.N375D on NM_001149.3) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55086400; called by muse, mutect2, varscan2
- ANKRD26 | c.5095G>T p.E1699* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV65774301; called by muse, mutect2, varscan2
- ANKRD35 | c.2666C>A p.A889D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV62911819; called by mutect2, varscan2
- ANO1 | c.1841A>G p.K614R | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV60290281; called by muse, mutect2, varscan2
- AP3B2 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV55615568; called by muse, mutect2
- APOB | c.11989A>C p.I3997L | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV51956609; called by muse, mutect2, varscan2
- APOB | c.11173G>T p.V3725F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV51951836, COSV51956623; called by muse, mutect2
- APOB | c.5282G>T p.G1761V | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51956641; called by muse, mutect2, varscan2
- ARAP2 | c.1488A>T p.G496= | Splice Region (SNP) | VAF 18/29 reads (62%) | catalogued as COSV58293715; called by muse, mutect2, varscan2
- ARAP2 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV58293723; called by muse, mutect2, varscan2
- AREG | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV52645245; called by muse, mutect2, varscan2
- ARFGEF2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568712014, COSV64212675; called by muse, mutect2, varscan2
- ARHGEF10L | c.3731G>T p.G1244V | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51442468; called by muse, mutect2, varscan2
- ARHGEF11 | c.4484A>C p.H1495P | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV59359366; called by muse, mutect2, varscan2
- ARHGEF12 | c.4013G>T p.R1338L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as COSV63105097, COSV63107934; called by muse, mutect2, varscan2
- ARHGEF17 | c.3501C>A p.N1167K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55239327; called by muse, mutect2, varscan2
- ARMC2 | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV64553717; called by muse, mutect2, varscan2
- ASB5 | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.856); catalogued as COSV56675014, COSV99641433; called by muse, mutect2, varscan2
- ASCC3 | c.4697G>T p.R1566L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV64982138; called by muse, mutect2, varscan2
- ASIC3 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs967503213, COSV52511527; called by muse, mutect2, varscan2
- ASIC4 | c.1022C>G p.S341C (on ENST00000347842 / NM_182847.3; = p.S360C on NM_018674.6) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV61733880; called by muse, mutect2, varscan2
- ASTN1 | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56089569; called by muse, mutect2, varscan2
- ASXL3 | c.5294C>A p.P1765Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52482520; called by muse, mutect2, varscan2
- ASXL3 | c.6229A>T p.S2077C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52482530; called by muse, mutect2, varscan2
- ATAD3A | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59236644; called by muse, mutect2, varscan2
- ATF6B | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV64352832; called by muse, mutect2, varscan2
- ATP8B2 | c.2282G>T p.G761V (on ENST00000672630; = p.G728V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV59249723; called by muse, mutect2, varscan2
- ATRNL1 | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV61819469; called by muse, mutect2, varscan2
- B3GAT2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57775591; called by muse, mutect2, varscan2
- BAAT | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52291345; called by muse, mutect2, varscan2
- BACH2 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57610512, COSV57611676; called by muse, mutect2, varscan2
- BCAN | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV61260129; called by muse, mutect2, varscan2
- BCL6 | c.654G>T p.M218I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.885); catalogued as COSV51656380; called by muse, mutect2, varscan2
- BDP1 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV62430772, COSV62435640; called by muse, mutect2, varscan2
- BICC1 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as COSV54067612; called by muse, mutect2, varscan2
- BMP2K | c.2203A>T p.K735* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55012484; called by muse, mutect2, varscan2
- BMS1 | c.2875A>T p.I959F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65735805; called by muse, mutect2, varscan2
- BRAF | c.1814+1G>A p.X605_splice (on ENST00000288602 / NM_001374244.1; = p.X565_splice on NM_004333.6 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/88 reads (15%) | catalogued as COSV56269442, COSV56419236; called by muse, mutect2, varscan2
- BRWD3 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as rs1569271167, COSV64754499; called by muse, mutect2, varscan2
- BSN | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767112247, COSV56520151; called by mutect2, varscan2
- BTBD9 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58437590; called by muse, mutect2, varscan2
- C14orf180 | c.276G>T p.R92S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV59558034; called by muse, mutect2, varscan2
- C14orf28 | c.232A>T p.R78W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV57334316; called by muse, mutect2, varscan2
- C19orf12 | c.142G>T p.A48S (on ENST00000392278 / NM_001031726.3; = p.A37S on NM_031448.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs777984856, CM132610, COSV100080678; called by muse, mutect2, varscan2
- C1QB | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245311, COSV59246247; called by muse, mutect2, varscan2
- C4orf50 | c.782T>A p.I261N (on ENST00000324058; = p.I1493N on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV60691043; called by muse, mutect2, varscan2
- C6 | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54709491, COSV99667987; called by muse, mutect2
- C7orf26 | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV60420859; called by muse, mutect2, varscan2
- C9orf72 | c.1424G>T p.R475L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as rs750045383, COSV66164185; called by muse, mutect2, varscan2
- CACNA1S | c.1626G>A p.W542* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs747128937, COSV62944788; called by muse, mutect2, varscan2
- CACNA2D1 | c.2533A>T p.S845C (on ENST00000356253 / NM_001366867.1; = p.S833C on NM_000722.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.907); catalogued as COSV62395465; called by muse, mutect2
- CALD1 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1303981785, COSV62655482; called by muse, mutect2, varscan2
- CAMSAP2 | c.3578C>T p.T1193I (on ENST00000236925 / NM_001297707.2; = p.T1182I on NM_203459.3) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV52678987; called by muse, mutect2, varscan2
- CAPZA3 | c.236del p.G79Afs*23 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as COSV99856890; called by mutect2, pindel, varscan2
- CARD17 | c.275-1G>C p.X92_splice | Splice Site (SNP) | VAF 13/40 reads (33%) | catalogued as COSV65215812; called by muse, mutect2, varscan2
- CASKIN1 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs763277416, COSV58877848; called by muse, mutect2, varscan2
- CASP8 | c.983G>T p.G328V (on ENST00000432109 / NM_033355.3; = p.G345V on NM_001228.4) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51848755, COSV51861035; called by muse, mutect2, varscan2
- CAVIN2 | c.681G>T p.R227S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58426270; called by muse, mutect2, varscan2
- CCDC126 | c.165A>T p.R55S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV56741406; called by muse, mutect2, varscan2
- CCDC14 | c.1108G>T p.D370Y (on ENST00000488653; = p.D322Y on NM_022757.5) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV59948549; called by muse, mutect2, varscan2
- CCDC141 | c.3292A>T p.K1098* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55384369; called by muse, mutect2, varscan2
- CCDC171 | c.3811G>A p.D1271N | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV66244967; called by muse, mutect2, varscan2
- CCDC96 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100027869; called by muse, mutect2, varscan2
- CCL13 | c.241T>A p.W81R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56775812; called by muse, mutect2, varscan2
- CCL17 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV54665344; called by muse, mutect2, varscan2
- CCNE1 | c.462+1G>T p.X154_splice | Splice Site (SNP) | VAF 15/103 reads (15%) | catalogued as COSV52906117; called by muse, mutect2, varscan2
- CD200R1 | c.282G>T p.E94D (on ENST00000471858 / NM_170780.3; = p.E117D on NM_138806.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55604755, COSV99867868; called by muse, mutect2, varscan2
- CDC42BPA | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62024351; called by muse, mutect2, varscan2
- CDC42BPG | c.3961G>C p.G1321R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs564259637, COSV100712183; called by muse, mutect2, varscan2
- CDC42BPG | c.3960G>T p.M1320I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100712021, COSV100712186; called by muse, mutect2, varscan2
- CDCA3 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV57530636; called by muse, mutect2, varscan2
- CDH10 | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52597939; called by muse, mutect2, varscan2
- CDH10 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 27/209 reads (13%) | catalogued as COSV52570770, COSV52593647; called by muse, mutect2, varscan2
- CDH12 | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV66456137; called by muse, mutect2, varscan2
- CDH18 | c.693T>A p.H231Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV56968887; called by muse, mutect2, varscan2
- CDH2 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99298981; called by muse, mutect2, varscan2
- CDH2 | c.1903G>T p.G635* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99298986; called by muse, mutect2, varscan2
- CDH5 | c.2027C>A p.P676H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as COSV58520463; called by muse, mutect2, varscan2
- CDH9 | c.1915C>A p.Q639K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.909); catalogued as COSV50527409; called by muse, mutect2, varscan2
- CELSR2 | c.2389G>T p.D797Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54780672; called by muse, mutect2, varscan2
- CENPF | c.1308G>C p.Q436H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65279892; called by muse, mutect2, varscan2
- CEP112 | c.2348A>T p.E783V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV67136953, COSV67145385; called by muse, mutect2, varscan2
- CEP120 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV60269168; called by muse, mutect2, varscan2
- CEP128 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV55393188; called by muse, mutect2, varscan2
- CFAP100 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV61504920; called by muse, mutect2
- CFAP70 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV60287518; called by muse, mutect2
- CFAP74 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.283); catalogued as COSV54575279; called by muse, mutect2, varscan2
- CFAP77 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs758203447, COSV100545685, COSV100546222; called by muse, mutect2, varscan2
- CFAP91 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV56341867, COSV56345510; called by muse, mutect2, varscan2
- CFHR3 | c.955T>A p.C319S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV66403478; called by muse, mutect2, varscan2
- CGAS | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV64809127; called by muse, mutect2, varscan2
- CHAT | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV60334982; called by mutect2, varscan2
- CHD7 | c.6791G>A p.R2264K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV71115411; called by muse, mutect2
- CHMP6 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57327213; called by muse, mutect2, varscan2
- CHRM2 | c.1394_1395insT p.R466Kfs*? (on ENST00000320658 / NM_001006632.3; = p.R466Kfs*6 on NM_000739.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 23/78 reads (29%) | catalogued as COSV100282161; called by mutect2, pindel, varscan2
- CHRM4 | c.641T>A p.L214Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63127655; called by muse, mutect2
- CHRNA1 | c.1357C>T p.H453Y (on ENST00000261007 / NM_001039523.3; = p.H428Y on NM_000079.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53685837; called by muse, mutect2, varscan2
- CHRNB2 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV63809644; called by muse, mutect2, varscan2
- CILK1 | c.1733T>C p.V578A (on ENST00000350082 / NM_001375397.1; = p.V571A on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV63156366; called by muse, mutect2
- CKAP5 | c.4219A>G p.N1407D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV56375214; called by muse, mutect2, varscan2
- CLCN3 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV61627114; called by muse, mutect2, varscan2
- CLEC12B | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58864686; called by muse, mutect2, varscan2
- CLEC16A | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV68502439; called by muse, mutect2, varscan2
- CLEC3A | c.379G>T p.G127C (on ENST00000651443; = p.G118C on NM_005752.6) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs1281075494, COSV55224250; called by muse, mutect2, varscan2
- CNTNAP2 | c.2903C>T p.T968I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1255422619, COSV62269860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.3688C>A p.P1230T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.614); catalogued as COSV62269865; called by muse, mutect2, varscan2
- CNTNAP5 | c.2378T>A p.V793D | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV101443389, COSV70516899; called by muse, mutect2, varscan2
- COL12A1 | c.3350A>T p.Y1117F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59410304; called by muse, mutect2, varscan2
- COL14A1 | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52871318; called by muse, mutect2, varscan2
- COL17A1 | c.2966T>A p.M989K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62229987; called by muse, mutect2, varscan2
- COL1A2 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV51967877; called by muse, mutect2
- COL4A4 | c.4182G>A p.M1394I | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV61637399; called by muse, mutect2, varscan2
- COL4A5 | c.4289G>T p.G1430V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60359038, COSV60374126; called by muse, mutect2, varscan2
- COL5A1 | c.2233-1G>T p.X745_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | catalogued as COSV65676207; called by muse, mutect2, varscan2
- COL5A3 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1402020774, COSV53420823; called by muse, mutect2, varscan2
- COL6A3 | c.4357G>T p.A1453S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV55114275; called by muse, mutect2, varscan2
- COL9A1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV61838646; called by muse, mutect2, varscan2
- COL9A1 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1386751621, COSV61838657; called by muse, mutect2, varscan2
- COMP | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs1166606479, COSV55876778; called by muse, mutect2, varscan2
- COP1 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.982); catalogued as COSV58178270; called by muse, mutect2, varscan2
- CPE | c.963C>A p.S321R | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68583023; called by muse, mutect2, varscan2
- CPEB2 | c.1967C>A p.P656Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52596198; called by muse, mutect2, varscan2
- CPED1 | c.2818G>T p.G940W | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121602, COSV60014361; called by muse, varscan2
- CPED1 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121722; called by muse, varscan2
- CPN1 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV64942895; called by muse, mutect2, varscan2
- CPNE7 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV52017101; called by muse, mutect2
- CPSF1 | c.2606A>G p.Q869R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV58235938; called by muse, mutect2, varscan2
- CROCC | c.4525G>C p.G1509R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.222); catalogued as COSV100978452, COSV65015349; called by muse, mutect2, varscan2
- CROT | c.1426-2A>T p.X476_splice | Splice Site (SNP) | VAF 21/144 reads (15%) | catalogued as COSV58977344; called by muse, mutect2, varscan2
- CRYBA1 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56601651; called by muse, mutect2, varscan2
- CSMD1 | c.8133C>G p.F2711L (on ENST00000520002; = p.F2710L on NM_033225.6) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV59396492; called by muse, mutect2, varscan2
- CSMD3 | c.9392C>A p.T3131K (on ENST00000297405 / NM_001363185.1; = p.T2962K on NM_052900.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV52345991; called by muse, varscan2
- CSMD3 | c.5129G>T p.G1710V (on ENST00000297405 / NM_001363185.1; = p.G1606V on NM_052900.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52175562, COSV52346020; called by muse, mutect2, varscan2
- CSMD3 | c.4202G>T p.R1401M (on ENST00000297405 / NM_001363185.1; = p.R1297M on NM_052900.3) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52346033; called by muse, mutect2, varscan2
- CSN2 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61992355, COSV61992857; called by muse, mutect2, varscan2
- CSNK1A1L | c.378C>A p.Y126* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV65790416; called by muse, mutect2, varscan2
- CSPG4 | c.1331C>A p.T444K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100414285; called by muse, mutect2, varscan2
- CSPG4 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs141025839; called by muse, mutect2, varscan2
- CSRNP3 | c.646T>A p.C216S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58786943; called by muse, mutect2, varscan2
- CTDSP2 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV66080316; called by muse, mutect2, varscan2
- CXorf66 | c.54G>T p.M18I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65169028, COSV65169894; called by muse, mutect2, varscan2
- CYB5R4 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.251); catalogued as COSV63752599; called by muse, mutect2, varscan2
- CYP11B2 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs574581657, COSV59995257; called by muse, mutect2, varscan2
- CYP27C1 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV58868815; called by muse, mutect2, varscan2
- CYP46A1 | c.781del p.R261Afs*5 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV55896315; called by mutect2, pindel, varscan2
- CYP4A22 | c.784C>A p.H262N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV53742947; called by muse, mutect2, varscan2
- CYSLTR2 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56167267; called by muse, mutect2, varscan2
- DAAM1 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV62840329; called by muse, mutect2, varscan2
- DAB2 | c.1962G>T p.M654I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57919725; called by muse, mutect2, varscan2
- DACH1 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV100499529; called by muse, varscan2
- DAPK2 | c.872A>T p.Q291L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56049106; called by muse, mutect2, varscan2
- DBH | c.187T>C p.W63R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249798572, COSV55042610; called by muse, mutect2, varscan2
- DCAF4L2 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV60483375; called by muse, mutect2, varscan2
- DCC | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV59095079, COSV59142839; called by muse, mutect2, varscan2
- DCHS1 | c.1670C>A p.P557H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs372255060, COSV55044235; called by muse, mutect2, varscan2
- DCLK1 | c.2018C>A p.P673H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV55215730; called by muse, mutect2, varscan2
- DCSTAMP | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52580650, COSV99886168; called by muse, mutect2, varscan2
- DDB2 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57041044; called by muse, mutect2, varscan2
- DDN | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60295101; called by muse, mutect2, varscan2
- DDX18 | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV54309570; called by muse, mutect2, varscan2
- DDX5 | c.1591C>G p.Q531E | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.056); catalogued as COSV56751729; called by muse, mutect2, varscan2
- DEFB110 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.25); catalogued as COSV64485075; called by muse, mutect2, varscan2
- DENND2C | c.2717C>T p.S906L (on ENST00000393274 / NM_001256404.2; = p.S849L on NM_198459.4) | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs1376526638, COSV67924424; called by muse, mutect2, varscan2
- DENND2C | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67924434; called by muse, mutect2, varscan2
- DEPTOR | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV53822996; called by muse, mutect2, varscan2
- DGKB | c.196T>C p.F66L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51825654; called by muse, mutect2
- DGKI | c.3021C>A p.N1007K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV55980820; called by muse, mutect2, varscan2
- DIAPH3 | c.3166G>A p.G1056S (on ENST00000400324 / NM_001042517.2; = p.G793S on NM_030932.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV57383130; called by muse, mutect2, varscan2
- DISP2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs866801308, COSV51148152; called by muse, mutect2
- DLG4 | c.242G>T p.G81V (on ENST00000399506 / NM_001321075.3; = p.G124V on NM_001365.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100264106; called by muse, mutect2
- DLG4 | c.241G>T p.G81C (on ENST00000399506 / NM_001321075.3; = p.G124C on NM_001365.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100264109; called by muse, mutect2
- DNAH1 | c.7234C>T p.L2412F | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as COSV70237828; called by muse, mutect2, varscan2
- DNAH11 | c.5503C>G p.H1835D | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60986686; called by muse, mutect2
- DNAH3 | c.7261C>T p.R2421C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776772766, COSV54513779; called by muse, mutect2, varscan2
- DNAH5 | c.10933A>G p.R3645G | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54257668; called by muse, mutect2
- DNAH9 | c.8061+2T>C p.X2687_splice | Splice Site (SNP) | VAF 23/97 reads (24%) | catalogued as COSV52381320; called by muse, mutect2, varscan2
- DNAJC6 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54779323, COSV54783062; called by muse, mutect2, varscan2
- DNAJC8 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55283651; called by muse, mutect2, varscan2
- DNMBP | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60634393; called by muse, mutect2, varscan2
- DOCK1 | c.4262T>G p.V1421G | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54763992; called by muse, mutect2, varscan2
- DOCK2 | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs535531464, COSV56990353; called by muse, varscan2
- DOCK3 | c.5159A>T p.N1720I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV56554639; called by muse, mutect2, varscan2
- DPY19L2 | c.1565C>G p.T522R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as COSV60546392; called by muse, mutect2, varscan2
- DPY19L2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV60546401; called by muse, mutect2, varscan2
- DPY19L4 | c.1631A>T p.E544V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV68964004; called by muse, mutect2
- DPYD | c.2623A>C p.K875Q | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs201035051, COSV64600307; called by muse, mutect2
- DSCAM | c.3015G>T p.W1005C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261762; called by muse, mutect2, varscan2
- DYNC1H1 | c.13738G>C p.A4580P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.131); catalogued as COSV100795608, COSV64143956; called by muse, mutect2, varscan2
- DZIP1L | c.1841C>A p.P614Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59524030; called by muse, mutect2
- EDIL3 | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV56900382, COSV56906986; called by muse, mutect2, varscan2
- EFNB3 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV56835088, COSV99872675; called by muse, mutect2, varscan2
- EGF | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954524553, COSV54485852, COSV99491572; called by muse, mutect2, varscan2
- EGFR | c.2763C>A p.S921R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs770529788, COSV51829394; called by muse, mutect2, varscan2
- EGLN2 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as COSV58281467; called by muse, mutect2, varscan2
- EIF3B | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62805418; called by muse, mutect2, varscan2
- ELMO1 | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV60329127; called by muse, mutect2, varscan2
- ENOPH1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56732555; called by muse, mutect2, varscan2
- ENOX1 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.092); catalogued as COSV54922039, COSV99816021; called by muse, mutect2, varscan2
- EPC2 | c.1081A>C p.N361H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV51550796; called by muse, mutect2, varscan2
- EPHA4 | c.2103C>A p.Y701* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56038374, COSV56045904; called by muse, mutect2, varscan2
- EPN1 | c.820G>T p.D274Y (on ENST00000270460 / NM_001321263.1; = p.D249Y on NM_013333.3) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV50046783; called by muse, mutect2, varscan2
- ERCC4 | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61312323, COSV61313791; called by muse, mutect2, varscan2
- ERICH3 | c.3400G>T p.A1134S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs533198887, COSV58606852; called by muse, mutect2
- ERICH6 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs746306034, COSV55800316; called by muse, mutect2, varscan2
- ESCO2 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV59416948; called by muse, mutect2
- ETS2 | c.1232A>C p.K411T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs777392517, COSV62874751; called by muse, mutect2, varscan2
- EVC2 | c.2586G>C p.M862I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV100186336, COSV60404781; called by muse, mutect2, varscan2
- EXO1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV62220341; called by muse, mutect2, varscan2
- EXOC4 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.728); catalogued as COSV54127002; called by muse, mutect2, varscan2
- F13A1 | c.173G>T p.W58L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV53569386; called by muse, mutect2, varscan2
- F8 | c.5717A>G p.K1906R | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV64279652; called by muse, mutect2, varscan2
- FAAP100 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59888180; called by muse, mutect2, varscan2
- FAM131B | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369986674, COSV58375195; called by muse, varscan2
- FAM171B | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59010066; called by muse, mutect2, varscan2
- FAM241A | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59038761; called by muse, mutect2, varscan2
- FAM47B | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.072); catalogued as COSV61457212; called by muse, mutect2, varscan2
- FAM47B | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61456932; called by muse, mutect2, varscan2
- FAM71A | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV54237869; called by muse, mutect2, varscan2
- FANCM | c.3619A>T p.R1207* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57507682; called by muse, mutect2, varscan2
- FANK1 | c.701G>C p.C234S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64159059; called by muse, mutect2
- FARP1 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV60350462; called by muse, mutect2, varscan2
- FAT1 | c.12980G>T p.S4327I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV71676292; called by muse, mutect2, varscan2
- FAT1 | c.3125C>T p.T1042I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs765144840, COSV71676293; called by muse, mutect2, varscan2
- FAT3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53186377; called by muse, mutect2, varscan2
- FAT3 | c.9082G>C p.V3028L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs1238952947, COSV53186430; called by muse, mutect2, varscan2
- FBLL1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV57924708; called by muse, mutect2, varscan2
- FBN2 | c.5950G>C p.V1984L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV52532513, COSV52549529; called by muse, mutect2, varscan2
- FBN2 | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52549545; called by muse, mutect2, varscan2
- FBXL2 | c.871A>C p.M291L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as COSV52143529; called by muse, mutect2, varscan2
- FBXL7 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61654635; called by muse, mutect2
- FBXL7 | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.626); catalogued as rs1318766367, COSV61654639; called by muse, mutect2
- FBXO30 | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52792742; called by muse, mutect2, varscan2
- FCRL3 | c.1136C>A p.P379Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63845558; called by muse, mutect2, varscan2
- FCRL5 | c.1804C>A p.H602N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV62511879, COSV62512606; called by muse, mutect2, varscan2
- FCRLB | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61060805; called by muse, mutect2, varscan2
- FERD3L | c.399C>G p.Y133* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV51762499, COSV51764707; called by muse, mutect2, varscan2
- FGB | c.307-1G>A p.X103_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV57419786; called by muse, mutect2, varscan2
- FGF13 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.469); catalogued as COSV59544278; called by muse, mutect2, varscan2
- FGF6 | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV57404384, COSV57405588; called by muse, varscan2
- FLG | c.11905C>A p.Q3969K | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.088); catalogued as COSV64251594; called by muse, mutect2, varscan2
- FLG | c.11587G>T p.V3863F | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs553373171, COSV64251601; called by muse, mutect2, varscan2
- FLG | c.5624G>T p.G1875V | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64251610; called by muse, mutect2, varscan2
- FLG | c.3089G>C p.G1030A | Missense Mutation (SNP) | VAF 279/618 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.258); catalogued as COSV64251614; called by muse, mutect2, varscan2
- FLNC | c.2513C>G p.A838G | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as rs775085661, COSV57958345, COSV57966882; called by muse, mutect2, varscan2
- FLNC | c.5387G>T p.G1796V | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57966899; called by muse, mutect2, varscan2
- FLT1 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.056); catalogued as COSV56745620; called by muse, mutect2, varscan2
- FLT4 | c.3538-2A>T p.X1180_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV56125048; called by muse, mutect2
- FMN1 | c.2580G>T p.M860I (on ENST00000616417 / NM_001277313.2; = p.M637I on NM_001103184.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57935373; called by muse, mutect2, varscan2
- FMN2 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60420596, COSV60458792; called by muse, mutect2, varscan2
- FRG2C | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV57312891; called by muse, mutect2
- FSTL5 | c.2410G>T p.G804C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60185167, COSV60236545; called by muse, mutect2, varscan2
- FTSJ3 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV63791650; called by muse, mutect2, varscan2
- FYN | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57622343; called by muse, mutect2, varscan2
- FZR1 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1412327723, COSV58054383; called by muse, mutect2, varscan2
- GAA | c.1396del p.V466Ffs*11 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as COSV100163305; called by mutect2, pindel, varscan2
- GABRA4 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.572); catalogued as COSV51936488; called by muse, mutect2, varscan2
- GABRG1 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV54963078; called by muse, mutect2, varscan2
- GABRG2 | c.1238A>G p.K413R (on ENST00000361925 / NM_001375343.1; = p.K373R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as COSV62723295; called by muse, mutect2, varscan2
- GABRP | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54666212; called by muse, mutect2, varscan2
- GABRP | c.680-1G>A p.X227_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV54666219; called by muse, mutect2, varscan2
- GALNT17 | c.1364C>A p.P455Q | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61196881; called by muse, mutect2, varscan2
- GCM2 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65276383, COSV65276761; called by muse, mutect2, varscan2
- GFRA1 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV62611841; called by muse, mutect2
- GFRAL | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs772537362, COSV61236481; called by muse, mutect2, varscan2
- GJA5 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.844); catalogued as rs371086800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLG1 | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52675723; called by muse, mutect2, varscan2
- GMDS | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66443256; called by muse, mutect2, varscan2
- GOLGA3 | c.3622C>T p.H1208Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52633217; called by muse, mutect2, varscan2
- GPATCH4 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV58040836; called by muse, mutect2, varscan2
- GPBP1 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.419); catalogued as COSV53311583; called by muse, mutect2, varscan2
- GPR158 | c.2127G>T p.L709F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66272094; called by muse, mutect2, varscan2
- GPR85 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV51785755; called by muse, mutect2, varscan2
- GPRC6A | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV59956500; called by muse, mutect2, varscan2
- GRIK1 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs1356851760, COSV58735054; called by muse, mutect2, varscan2
- GRIK1 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV58735077; called by muse, mutect2, varscan2
- GRIP1 | c.2543C>A p.P848Q (on ENST00000359742 / NM_001379345.1; = p.P796Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV54046308; called by muse, mutect2
- GRM1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51375234; called by muse, mutect2, varscan2
- GRM1 | c.884C>A p.T295K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV51249111; called by muse, mutect2, varscan2
- GRPR | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs776352760, COSV66670389; called by muse, mutect2, varscan2
- GSTA1 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 22/134 reads (16%) | catalogued as COSV58017262; called by muse, varscan2
- GTDC1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.862); catalogued as COSV54008211; called by muse, mutect2, varscan2
- GTPBP4 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52989471; called by muse, mutect2, varscan2
- GYPA | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV51626330; called by muse, mutect2, varscan2
- GYPC | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV52149164; called by muse, mutect2
- GZMH | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99362111; called by muse, mutect2, varscan2
- HAPLN1 | c.1043A>T p.Y348F | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.914); catalogued as COSV57152662; called by muse, mutect2, varscan2
- HAVCR2 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57155100; called by muse, mutect2, varscan2
- HBD | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM820009, COSV53081910, COSV53083920; called by muse, mutect2, varscan2
- HCN1 | c.1997C>G p.P666R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV100299771, COSV57492798, COSV57541621; called by muse, mutect2, varscan2
- HDHD5 | c.178G>A p.G60S (on ENST00000336737 / NM_033070.3; = p.G30S on NM_017829.5) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50097043; called by muse, mutect2, varscan2
- HEATR5B | c.447+1G>T p.X149_splice | Splice Site (SNP) | VAF 22/30 reads (73%) | catalogued as COSV51860243; called by muse, mutect2, varscan2
- HECTD4 | c.10219G>A p.D3407N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as COSV66401198; called by muse, mutect2, varscan2
- HGF | c.1244G>T p.W415L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55946608, COSV55952188, COSV99737896; called by muse, varscan2
- HGF | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55958411; called by muse, varscan2
- HGF | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.616); catalogued as COSV55958434; called by muse, varscan2
- HGFAC | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs776595513, COSV58758058; called by muse, mutect2, varscan2
- HHIPL1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV58090261, COSV58094104; called by muse, mutect2, varscan2
- HIVEP2 | c.6444G>T p.R2148S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV50086933; called by muse, mutect2, varscan2
- HIVEP3 | c.4613C>A p.S1538Y | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV56025493; called by muse, mutect2
- HJV | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV60953435; called by muse, mutect2, varscan2
- HMCN1 | c.9781G>T p.G3261* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV54948578; called by muse, mutect2, varscan2
- HNRNPA3 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 13/194 reads (7%) | catalogued as COSV66821249; called by muse, mutect2
- HNRNPR | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV56424280, COSV56424791; called by muse, mutect2, varscan2
- HOXA1 | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV56068064; called by muse, mutect2, varscan2
- HOXB1 | c.898A>C p.T300P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV99495739; called by muse, mutect2, varscan2
- HOXB1 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53318040; called by muse, mutect2
- HSD3B2 | c.417C>A p.N139K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs369303483, COSV65594213; called by muse, mutect2, varscan2
- HSF5 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV60420154; called by muse, mutect2, varscan2
- HTR2C | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.491); catalogued as COSV52226936; called by muse, mutect2, varscan2
- HTR6 | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.193); catalogued as COSV57035015; called by muse, mutect2, varscan2
- HYOU1 | c.2888G>T p.G963V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV68217584; called by muse, mutect2
- IAPP | c.255T>G p.N85K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV53714868; called by muse, varscan2
- IAPP | c.259T>A p.L87M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV53713321, COSV53714406; called by muse, varscan2
- ID2 | c.384C>G p.D128E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1451198304, COSV52171162; called by muse, mutect2, varscan2
- IFI44 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.904); catalogued as COSV66075973; called by muse, mutect2, varscan2
- IFNK | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51791908; called by muse, mutect2, varscan2
- IFRD1 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1434905030, COSV50045667; called by muse, mutect2, varscan2
- IL16 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57269183; called by muse, mutect2, varscan2
- IL16 | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV57269195; called by muse, mutect2, varscan2
- IL17A | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60684141, COSV60685655; called by muse, mutect2, varscan2
- IL1RL1 | c.1274T>A p.L425Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV52121472; called by muse, mutect2, varscan2
- INHA | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV54731140; called by muse, mutect2, varscan2
- INSL4 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53330088; called by muse, mutect2, varscan2
- INSR | c.3136A>C p.I1046L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV57174923; called by muse, mutect2, varscan2
- INTS11 | c.126+1G>T p.X42_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as COSV59673525; called by muse, mutect2, varscan2
- IQSEC1 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV56230859; called by muse, mutect2, varscan2
- IRAG1 | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV70213249; called by muse, mutect2
- ITFG2 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 47/233 reads (20%) | catalogued as COSV57388970, COSV57390102, COSV57391435; called by muse, mutect2, varscan2
- ITGA7 | c.2086G>T p.A696S (on ENST00000555728; = p.A652S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs372579627; called by muse, mutect2, varscan2
- ITGA8 | c.2373-2A>T p.X791_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV65237537; called by muse, mutect2, varscan2
- ITGA8 | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65223930; called by muse, mutect2, varscan2
- ITGA8 | c.567C>G p.N189K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1230810399, COSV65237549; called by muse, mutect2, varscan2
- ITGB3 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71383459, COSV71385359; called by muse, mutect2, varscan2
- ITSN1 | c.1874T>C p.M625T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs1266460178, COSV66086863; called by muse, mutect2, varscan2
- ITSN1 | c.4537T>A p.Y1513N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67157743; called by muse, mutect2, varscan2
- IZUMO1 | c.815C>A p.A272E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.416); catalogued as COSV55808935; called by muse, mutect2, varscan2
- JPH3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298741562, COSV52472482; called by muse, mutect2, varscan2
- KCNA4 | c.1007G>T p.R336M | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV60256257, COSV60256575; called by muse, mutect2, varscan2
- KCNAB2 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV51236290, COSV51239998; called by muse, mutect2, varscan2
- KCNH4 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52921691; called by muse, mutect2, varscan2
- KCNH5 | c.2651C>A p.P884Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV59781173; called by muse, mutect2, varscan2
- KCNH8 | c.2545C>G p.P849A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60479617; called by muse, mutect2, varscan2
- KCNH8 | c.3306C>A p.N1102K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as rs74606615, COSV60479621; called by muse, mutect2, varscan2
- KCNJ10 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV63635272; called by muse, mutect2, varscan2
- KCNJ2 | c.1168A>T p.S390C | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV54664315; called by muse, mutect2, varscan2
- KCNK10 | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as COSV56654102; called by muse, mutect2
- KDM3B | c.340A>T p.I114F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV58696328; called by muse, mutect2, varscan2
- KEL | c.903G>C p.M301I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV62336757; called by muse, mutect2
- KIAA1109 | c.4251A>T p.K1417N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52683130, COSV52696632; called by muse, mutect2, varscan2
- KIAA1109 | c.10975A>G p.T3659A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV52696665; called by muse, mutect2, varscan2
- KIF17 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs755947089, COSV56120013; called by muse, mutect2, varscan2
- KIF21B | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59768427; called by muse, mutect2, varscan2
- KIF5C | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV68484262; called by muse, mutect2, varscan2
- KIN | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59623182; called by muse, mutect2, varscan2
- KIT | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV55426128; called by muse, mutect2, varscan2
- KLF17 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64856941, COSV64857247; called by muse, mutect2, varscan2
- KLHL1 | c.327del p.Q110Rfs*16 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as COSV64783137; called by mutect2, pindel, varscan2
- KLHL11 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1455626392, COSV100044445, COSV59863271; called by muse, mutect2, varscan2
- KLHL4 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV64148976; called by muse, mutect2, varscan2
- KLKB1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs761769626, COSV52995460; called by muse, mutect2, varscan2
- KRT71 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV57293516; called by muse, mutect2, varscan2
- KRT79 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV57942756; called by muse, mutect2, varscan2
- KRTAP1-5 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV62624645; called by muse, varscan2
- KRTAP10-7 | c.517T>A p.C173S | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV59113948; called by muse, mutect2, varscan2
- KRTAP19-1 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV66861667; called by muse, mutect2, varscan2
- KRTAP23-1 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV61935847; called by muse, mutect2, varscan2
- L1CAM | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62830621; called by muse, mutect2, varscan2
- LAMA2 | c.1246T>A p.C416S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70356808; called by muse, mutect2, varscan2
- LAMA2 | c.3308G>T p.C1103F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70356812; called by muse, mutect2, varscan2
- LAMB2 | c.2343G>A p.L781= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV59738649; called by muse, mutect2, varscan2
- LAMC1 | c.4473+1G>T p.X1491_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV51187168; called by muse, mutect2, varscan2
- LAMP5 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV55717680; called by muse, mutect2, varscan2
- LBP | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV54144658; called by muse, mutect2, varscan2
- LEFTY1 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.408); catalogued as COSV55284348; called by muse, mutect2
- LEPR | c.2374G>C p.V792L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1286397229, COSV60766347; called by muse, mutect2, varscan2
- LGALS9B | c.864G>T p.W288C (on ENST00000423676 / NM_001367292.1; = p.W287C on NM_001042685.2) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60866080; called by muse, mutect2, varscan2
- LGR5 | c.1640C>G p.P547R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57010955; called by muse, mutect2, varscan2
- LGR6 | c.824A>T p.K275M (on ENST00000367278 / NM_001017403.1; = p.K223M on NM_021636.3) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV55167861; called by muse, mutect2, varscan2
- LGSN | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV65728910; called by muse, mutect2, varscan2
- LIG1 | c.1237A>T p.R413W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV54396749; called by muse, mutect2, varscan2
- LILRB4 | c.846C>A p.H282Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.365); catalogued as COSV54409258; called by muse, mutect2, varscan2
- LIMK2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs946756010, COSV59185075; called by muse, mutect2
- LINGO2 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58065440; called by muse, mutect2, varscan2
- LINGO4 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59096273; called by muse, mutect2, varscan2
- LMNA | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61544214; called by muse, mutect2, varscan2
- LNX2 | c.1991A>T p.H664L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV60339225; called by muse, mutect2
- LPO | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV51863350; called by muse, mutect2, varscan2
- LRAT | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.756); catalogued as COSV100312126, COSV60476402, COSV60478293; called by muse, mutect2, varscan2
- LRP1B | c.6179G>T p.R2060L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV67283743, COSV67287558; called by muse, mutect2, varscan2
- LRP1B | c.3058C>T p.P1020S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV67283748; called by muse, mutect2
- LRP2 | c.6628G>A p.G2210R | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55578763; called by muse, mutect2, varscan2
- LRRC66 | c.1278C>A p.Y426* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as rs776718025, COSV58632748, COSV58637301; called by muse, mutect2, varscan2
- LRRC7 | c.1168C>A p.L390I (on ENST00000651989 / NM_001370785.2; = p.L357I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50653148; called by muse, mutect2, varscan2
- LRRTM1 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV54447756; called by muse, mutect2, varscan2
- LTV1 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs926689969, COSV62536823; called by muse, mutect2
- LYRM2 | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs534210657, COSV65531925; called by muse, mutect2, varscan2
- MACF1 | c.15823G>C p.D5275H (on ENST00000372915; = p.D3208H on NM_012090.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV57149198; called by muse, mutect2, varscan2
- MACF1 | c.20735G>A p.R6912Q (on ENST00000372915; = p.R4957Q on NM_012090.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs756134944, COSV57103765; called by muse, mutect2, varscan2
- MAGEB4 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs756919640, COSV66775733; called by muse, mutect2, varscan2
- MAGI2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62704994; called by muse, varscan2
- MALT1 | c.1661T>C p.L554S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61936932; called by muse, mutect2, varscan2
- MAML1 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV52989369; called by muse, mutect2, varscan2
- MANEA | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62590829; called by muse, mutect2, varscan2
- MAP2K6 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV100765084, COSV63008243; called by muse, mutect2, varscan2
- MAP3K19 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV59642833; called by muse, mutect2, varscan2
- MAST1 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV52256692; called by muse, mutect2, varscan2
- MBIP | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59255521; called by muse, mutect2
- MBL2 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64759591; called by muse, mutect2
- MCF2 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as rs202133857, COSV58496604, COSV58496703; called by muse, mutect2, varscan2
- MED25 | c.2212A>T p.M738L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV57207925; called by muse, mutect2, varscan2
- MEGF10 | c.2057G>T p.R686I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1448285273, COSV57257726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL4 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60605121; called by muse, mutect2, varscan2
- MGA | c.1870A>T p.K624* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV54964699; called by muse, mutect2
- MGAT1 | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | PolyPhen probably damaging (0.984); catalogued as COSV57135659; called by muse, mutect2, varscan2
- MINDY4 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV54677157; called by muse, mutect2, varscan2
- MMP16 | c.1342G>T p.V448F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV54186061, COSV54193482; called by muse, mutect2, varscan2
- MMP16 | c.1126G>C p.G376R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54154390, COSV54193489; called by muse, mutect2, varscan2
- MMP2 | c.1273T>A p.Y425N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54606128; called by muse, mutect2, varscan2
- MMP2 | c.1610G>C p.G537A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV54604596, COSV54606146; called by muse, mutect2, varscan2
- MMP8 | c.903-1G>A p.X301_splice | Splice Site (SNP) | VAF 16/26 reads (62%) | catalogued as COSV52634626; called by muse, mutect2, varscan2
- MMRN1 | c.3341C>A p.P1114H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53343656, COSV99306375; called by muse, mutect2, varscan2
- MMS22L | c.1579G>T p.G527C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51527684; called by muse, mutect2, varscan2
- MORC3 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV68689545; called by muse, mutect2, varscan2
- MRGPRF | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57996584; called by muse, mutect2, varscan2
- MS4A4A | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV59701392; called by muse, mutect2, varscan2
- MSGN1 | c.226A>C p.S76R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV55264033; called by muse, mutect2, varscan2
- MTMR12 | c.1084T>A p.W362R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53788805; called by muse, mutect2, varscan2
- MTOR | c.5182G>T p.A1728S | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.983); catalogued as COSV63877798; called by muse, mutect2, varscan2
- MUC16 | c.28904C>T p.T9635I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV67500701; called by muse, mutect2, varscan2
- MUC16 | c.23903C>G p.T7968S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV67500710; called by muse, mutect2, varscan2
- MUC16 | c.17749A>T p.S5917C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as COSV67500732; called by muse, mutect2, varscan2
- MUC16 | c.12295C>A p.P4099T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV67500744; called by muse, mutect2, varscan2
- MUC16 | c.8814G>T p.R2938S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV67500752; called by muse, mutect2, varscan2
- MUC16 | c.7019C>A p.T2340K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV67500763; called by muse, mutect2, varscan2
- MUC17 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV59331689, COSV59332687; called by muse, mutect2, varscan2
- MUC17 | c.10067A>G p.E3356G | Missense Mutation (SNP) | VAF 90/629 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs1327825315, COSV60306947; called by muse, mutect2, varscan2
- MUC5AC | c.15650C>A p.P5217Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100611578, COSV100611641; called by muse, mutect2, varscan2
- MXRA5 | c.2420C>T p.T807I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV54254098; called by muse, mutect2, varscan2
- MYBPC1 | c.779C>A p.P260H (on ENST00000550270 / NM_206820.2; = p.P285H on NM_002465.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62252214, COSV62258399; called by muse, mutect2, varscan2
- MYF6 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV57353696, COSV57353820; called by muse, mutect2, varscan2
- MYH1 | c.3526C>A p.Q1176K | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV56858656; called by muse, mutect2, varscan2
- MYH2 | c.5618T>A p.L1873* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55450637; called by muse, mutect2, varscan2
- MYH3 | c.5425G>T p.G1809W | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56870963; called by muse, mutect2, varscan2
- MYH7 | c.3602C>A p.A1201D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100806841; called by muse, mutect2, varscan2
- MYH8 | c.2222G>C p.S741T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV67974095; called by muse, mutect2, varscan2
- MYL2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1555257777, COSV57407493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK2 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV65660118; called by muse, mutect2, varscan2
- MYO1C | c.2629G>T p.A877S (on ENST00000648651 / NM_001080779.2; = p.A842S on NM_033375.5) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV63001197; called by muse, mutect2, varscan2
- MYO5C | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV55912937; called by muse, varscan2
- MYO7A | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68687650; called by muse, mutect2, varscan2
- MYO7B | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373706003; called by muse, mutect2, varscan2
- MYO7B | c.951C>A p.D317E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.3); catalogued as COSV67349399, COSV67352884; called by muse, mutect2
- MYOM2 | c.3742C>G p.R1248G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV50729926, COSV50792917; called by muse, mutect2, varscan2
- MYPN | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV62741010; called by muse, mutect2, varscan2
- N4BP2 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV54708004; called by muse, mutect2, varscan2
- NANP | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV59160786; called by muse, mutect2, varscan2
- NAP1L1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV53876818; called by muse, mutect2, varscan2
- NAV3 | c.4415C>A p.A1472D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs1450103692, COSV57117298; called by muse, mutect2, varscan2
- NBEA | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59766496, COSV59830102; called by muse, mutect2, varscan2
- NCAN | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53060728; called by muse, mutect2, varscan2
- NCAPD3 | c.4240A>G p.S1414G | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73188011; called by muse, mutect2, varscan2
- NCAPD3 | c.2045G>T p.S682I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs746992785, COSV73259052; called by muse, mutect2, varscan2
- NCF1 | c.153T>A p.H51Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.903); catalogued as COSV56877553; called by muse, mutect2, varscan2
- NCKAP1L | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53213325; called by muse, mutect2, varscan2
- NCKIPSD | c.1351-1G>T p.X451_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53664224; called by muse, mutect2, varscan2
- NCOR1 | c.5662C>T p.P1888S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV52000081; called by muse, mutect2, varscan2
- NCSTN | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.079); catalogued as rs1285710472, COSV54110623; called by muse, mutect2, varscan2
- NDST4 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52124958; called by muse, mutect2, varscan2
- NEB | c.13105C>G p.L4369V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV51466825; called by muse, mutect2, varscan2
- NEB | c.7118A>T p.Q2373L | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51466851; called by muse, mutect2
- NECTIN4 | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV63514234; called by muse, mutect2, varscan2
- NEDD4 | c.3364G>A p.D1122N (on ENST00000508342 / NM_001284338.1; = p.D703N on NM_006154.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59065939; called by muse, mutect2, varscan2
- NEO1 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV56079237; called by muse, mutect2, varscan2
- NEXMIF | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs868183592, COSV50021548; called by muse, mutect2, varscan2
- NFATC3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60480904; called by muse, mutect2, varscan2
- NIBAN1 | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV62288357; called by muse, mutect2
- NIPBL | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.156); catalogued as COSV56969003; called by muse, mutect2, varscan2
- NKIRAS2 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV56918598; called by muse, mutect2, varscan2
- NLRC5 | c.1842G>T p.E614D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV52664579; called by muse, mutect2, varscan2
- NOS1 | c.2744G>A p.R915K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57622703; called by muse, mutect2, varscan2
- NOS3 | c.1321T>A p.C441S | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52496859; called by muse, mutect2, varscan2
- NOTCH4 | c.1949T>A p.L650H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1370839447, COSV66684542; called by muse, mutect2, varscan2
- NPAP1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV61512323; called by muse, mutect2, varscan2
- NPAS2 | c.2185G>T p.V729F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59557397, COSV59563156; called by muse, mutect2, varscan2
- NPEPPS | c.2315T>C p.M772T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs761544720, COSV59106302; called by muse, mutect2, varscan2
- NPFFR2 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV58148421; called by muse, mutect2
- NPHP4 | c.3532A>T p.N1178Y | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65398642; called by muse, mutect2, varscan2
- NRCAM | c.2496G>T p.E832D (on ENST00000379028 / NM_001371124.1; = p.E816D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV61051295; called by muse, mutect2, varscan2
- NRG3 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV64588197; called by muse, mutect2, varscan2
- NRG3 | c.1667G>A p.S556N (on ENST00000404547 / NM_001370084.1; = p.S532N on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV64560647; called by muse, mutect2, varscan2
- NRXN1 | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV58460381, COSV58500607; called by muse, mutect2, varscan2
- NTN3 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53549178; called by muse, mutect2, varscan2
- NTS | c.25_26insA p.L9Hfs*39 | Frame Shift Ins (INS) | VAF 23/86 reads (27%) | catalogued as COSV99755253; called by mutect2, pindel, varscan2
- NUP205 | c.4501G>C p.D1501H | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53667376; called by muse, mutect2, varscan2
- NUP210L | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV55159616; called by muse, mutect2, varscan2
- NUP35 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54559684; called by muse, mutect2, varscan2
- OBSCN | c.14023G>C p.G4675R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52762778, COSV52841444; called by muse, mutect2, varscan2
- OGDH | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV56058371; called by muse, mutect2, varscan2
- OLFM3 | c.425A>T p.H142L (on ENST00000338858 / NM_001288821.1; = p.H122L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.175); catalogued as COSV58805533, COSV99058322; called by muse, mutect2, varscan2
- OLFML2B | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.302); catalogued as COSV54201127; called by muse, varscan2
- OLFML2B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs759621817, COSV54195956; called by muse, varscan2
- OPN1SW | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50823718; called by muse, mutect2, varscan2
- OR10AG1 | c.233C>G p.T78S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV56635301; called by muse, mutect2, varscan2
- OR10J1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71129877; called by muse, mutect2, varscan2
- OR11G2 | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV62133296; called by muse, mutect2, varscan2
- OR11H12 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV73569230, COSV73569371; called by mutect2, varscan2
- OR14C36 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV58603140; called by muse, mutect2, varscan2
- OR2C3 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100825566, COSV63576627; called by muse, varscan2
- OR2G3 | c.788G>C p.S263T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV60682994; called by muse, mutect2, varscan2
- OR2L13 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV63549646, COSV63550162; called by muse, mutect2, varscan2
- OR2L3 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs755015872, COSV63454651, COSV63456579; called by muse, mutect2
- OR2L8 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV61728754; called by muse, mutect2
- OR2M3 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV71759362; called by muse, mutect2, varscan2
- OR2M5 | c.21del p.F8Sfs*123 | Frame Shift Del (DEL) | VAF 45/241 reads (19%) | catalogued as COSV63546282; called by mutect2, pindel, varscan2
- OR2T10 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as COSV100393702, COSV57896771; called by muse, mutect2, varscan2
- OR2T10 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100393854; called by muse, mutect2, varscan2
- OR4C15 | c.861del p.W287* (on ENST00000314644; = p.W233* on NM_001001920.2) | Frame Shift Del (DEL) | VAF 41/141 reads (29%) | catalogued as COSV58952146; called by mutect2, pindel, varscan2
- OR4C16 | c.257del p.K86Rfs*11 | Frame Shift Del (DEL) | VAF 44/223 reads (20%) | catalogued as COSV58940928; called by mutect2, varscan2
- OR4D1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52126395; called by muse, mutect2, varscan2
- OR4D5 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.045); catalogued as COSV58306997; called by muse, mutect2, varscan2
- OR4K1 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV53462733; called by muse, mutect2
- OR4K5 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60005601; called by muse, mutect2, varscan2
- OR4M1 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV60064017; called by muse, mutect2
- OR4S2 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777460276, COSV56748651; called by muse, mutect2, varscan2
- OR4S2 | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56748660; called by muse, mutect2, varscan2
- OR51V1 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.612); catalogued as COSV58316667; called by muse, mutect2, varscan2
- OR52M1 | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV64173096; called by muse, mutect2, varscan2
- OR52R1 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61889655; called by muse, mutect2, varscan2
- OR56A4 | c.512T>C p.M171T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs370029590; called by muse, mutect2, varscan2
- OR5A1 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57378780; called by muse, mutect2, varscan2
- OR5AK2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs767466763, COSV58805513; called by muse, mutect2, varscan2
- OR5AS1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100546152, COSV57983051; called by muse, mutect2, varscan2
- OR5AS1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs775842242, COSV57981863, COSV57983631; called by muse, mutect2, varscan2
- OR5AS1 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV57981088, COSV57983640; called by muse, mutect2, varscan2
- OR5B3 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.151); catalogued as rs1253869329, COSV58676477, COSV58678987; called by muse, mutect2, varscan2
- OR5D18 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV61735997; called by muse, mutect2, varscan2
- OR5L1 | c.16T>A p.C6S | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.584); catalogued as COSV61735737; called by muse, mutect2
- OR5L2 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV65725425; called by muse, mutect2, varscan2
- OR5M10 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV73242474; called by muse, varscan2
- OR5R1 | c.464T>G p.V155G | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV56573920; called by muse, mutect2
- OR6B1 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV68769987; called by muse, mutect2, varscan2
- OR6K2 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); catalogued as COSV62744382; called by muse, mutect2, varscan2
- OR6K2 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100656675, COSV62744108, COSV62744385; called by muse, mutect2, varscan2
- OR6K3 | c.968A>T p.Q323L (on ENST00000368146; = p.Q307L on NM_001005327.2) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63746707; called by muse, mutect2, varscan2
- OR6M1 | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58435108; called by muse, mutect2, varscan2
- OR8H1 | c.912G>C p.M304I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57296269; called by muse, mutect2, varscan2
- OR8J3 | c.764T>G p.M255R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV56884793; called by muse, mutect2, varscan2
- OR9G4 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57250123; called by muse, mutect2, varscan2
- OR9Q1 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59048744; called by muse, mutect2, varscan2
- ORC1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV65365449; called by muse, mutect2, varscan2
- OSMR | c.2518C>G p.L840V | Missense Mutation (SNP) | VAF 123/250 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.29); catalogued as COSV57093168, COSV99952944; called by muse, mutect2, varscan2
- OTOGL | c.6079G>T p.D2027Y (on ENST00000547103; = p.D2018Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100088079; called by muse, mutect2, varscan2
- OTULINL | c.907T>C p.F303L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57036987; called by muse, mutect2, varscan2
- OVCH1 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV99761457; called by muse, mutect2, varscan2
- PACRGL | c.706A>T p.I236F (on ENST00000471979; = p.I209F on NM_145048.5) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54845069; called by muse, mutect2, varscan2
- PALLD | c.3312G>C p.K1104N (on ENST00000505667 / NM_001166108.2; = p.K1087N on NM_016081.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54977811, COSV54997029; called by muse, mutect2, varscan2
- PALM | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52771495; called by muse, mutect2, varscan2
- PAMR1 | c.1574G>T p.G525V (on ENST00000619888 / NM_001001991.3; = p.G542V on NM_015430.4) | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53515182, COSV53517357; called by muse, mutect2
- PAN2 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV57753487, COSV57756500; called by muse, mutect2, varscan2
- PAPPA2 | c.3884C>A p.P1295Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.369); catalogued as COSV62814260; called by muse, mutect2, varscan2
- PAPPA2 | c.4237G>C p.G1413R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV62814267; called by muse, mutect2, varscan2
- PAPPA2 | c.5267G>C p.G1756A | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62800359, COSV62814272; called by muse, mutect2, varscan2
- PAPSS1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs867093052, COSV54494072; called by mutect2, varscan2
- PARP3 | c.1320C>G p.F440L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV67169078; called by muse, mutect2, varscan2
- PASD1 | c.67T>A p.W23R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV64858331; called by muse, mutect2, varscan2
- PCDH10 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV52088057, COSV52105960; called by muse, mutect2, varscan2
- PCDH11X | c.3941G>T p.S1314I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV53512742; called by muse, mutect2, varscan2
- PCDH15 | c.4647A>T p.R1549S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV64749052; called by muse, mutect2, varscan2
- PCDH15 | c.2612C>A p.T871K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57408742; called by muse, varscan2
- PCDH15 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.958); catalogued as COSV57321580; called by muse, varscan2
- PCDH17 | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932183; called by muse, mutect2, varscan2
- PCDH17 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.297); catalogued as COSV64980517; called by muse, mutect2
- PCDHGA10 | c.1820G>T p.W607L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99549282; called by muse, mutect2, varscan2
- PCDHGA10 | c.1821G>T p.W607C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV99549287; called by muse, mutect2, varscan2
- PCLO | c.12115G>C p.D4039H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61675290; called by muse, mutect2, varscan2
- PDE3A | c.2055T>G p.I685M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV62984458; called by muse, mutect2, varscan2
- PDE4DIP | c.2741G>T p.R914L | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57734313; called by muse, mutect2, varscan2
- PDGFRA | c.2394C>A p.F798L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57275539; called by muse, mutect2, varscan2
- PDGFRA | c.2848G>T p.V950L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.161); catalogued as COSV57275545; called by muse, mutect2, varscan2
- PDHA2 | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54782597; called by muse, mutect2, varscan2
- PDILT | c.957T>A p.N319K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56706199; called by muse, mutect2, varscan2
- PDS5B | c.1837A>G p.I613V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.327); catalogued as rs1475338159, COSV59735808; called by muse, mutect2, varscan2
- PDSS2 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358413173, COSV64650734; called by muse, mutect2, varscan2
- PDYN | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54102256, COSV54102710; called by muse, mutect2, varscan2
- PEBP4 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV56473079; called by muse, mutect2, varscan2
- PER1 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57922545; called by muse, varscan2
- PEX2 | c.740G>T p.C247F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63813796; called by muse, mutect2, varscan2
- PGBD1 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV52556598; called by muse, mutect2, varscan2
- PI15 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52641636, COSV52644813; called by muse, mutect2, varscan2
- PIEZO2 | c.7423G>T p.A2475S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV53295477; called by muse, mutect2, varscan2
- PIK3C2A | c.4954C>G p.L1652V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV56403030; called by muse, mutect2, varscan2
- PIK3C2G | c.2395C>A p.P799T (on ENST00000676171; = p.P758T on NM_004570.5) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56837995; called by muse, mutect2, varscan2
- PIKFYVE | c.3862G>T p.G1288C | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52250355; called by muse, mutect2, varscan2
- PKD1L1 | c.2311G>T p.V771L | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); catalogued as rs770386708, COSV56967598, COSV56980350; called by muse, mutect2, varscan2
- PKHD1L1 | c.5089C>T p.H1697Y | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV65755561; called by muse, mutect2, varscan2
- PLA2R1 | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV51788164; called by muse, mutect2
- PLCE1 | c.4758G>T p.E1586D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV53375664; called by muse, mutect2, varscan2
- PLCXD3 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1198701640, COSV60613948, COSV60620303; called by muse, mutect2
- PLPP4 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV64830014; called by muse, mutect2, varscan2
- PLPP4 | c.513T>A p.S171R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64830021; called by muse, mutect2, varscan2
- PLPPR4 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100926973; called by muse, mutect2, varscan2
- PLPPR4 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100926975; called by muse, mutect2, varscan2
- PLPPR5 | c.371-2A>T p.X124_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV54179729; called by muse, mutect2, varscan2
- PLXNA3 | c.2814C>G p.D938E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV63756085; called by muse, mutect2, varscan2
- PLXNA4 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.474); catalogued as COSV58165820; called by muse, mutect2, varscan2
- PM20D2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215213887, COSV51532324; called by muse, mutect2, varscan2
- PMEL | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59389171; called by muse, mutect2, varscan2
- POGK | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1267335685, COSV63311804; called by muse, mutect2, varscan2
- POLQ | c.6842G>T p.G2281V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs146701093, COSV51759235; called by muse, mutect2, varscan2
- POLQ | c.2393G>C p.R798P | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV51763297; called by muse, mutect2, varscan2
- PPHLN1 | c.1228T>G p.W410G | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs1349457987, COSV99872518; called by mutect2, varscan2
- PPP1R21 | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54290409; called by muse, mutect2, varscan2
- PPP1R3A | c.2417G>T p.R806L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as rs766322596, COSV52894665; called by muse, mutect2, varscan2
- PPY | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV56823863; called by muse, mutect2
- PRAMEF1 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV60020082; called by muse, mutect2, varscan2
- PRDM1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64844643; called by muse, mutect2, varscan2
- PRDM10 | c.1931A>G p.Y644C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58805928; called by muse, mutect2
- PRDM13 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs368251086, COSV65030836; called by muse, mutect2, varscan2
- PRDM14 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52575835; called by muse, mutect2, varscan2
- PRDM15 | c.2496G>T p.K832N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54160691; called by muse, mutect2, varscan2
- PRDM16 | c.1720G>C p.G574R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV54612208; called by muse, mutect2, varscan2
- PRG3 | c.536A>T p.D179V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54664923; called by muse, mutect2, varscan2
- PROS1 | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as CD128604, COSV62399881; called by muse, mutect2, varscan2
- PRR30 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53208542; called by muse, mutect2, varscan2
- PRUNE2 | c.1642A>C p.N548H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV65049211; called by mutect2, varscan2
- PSG11 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV60458459, COSV99072179; called by muse, mutect2, varscan2
- PSG4 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 89/156 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54942034; called by muse, mutect2, varscan2
- PSG7 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 100/184 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68446939; called by muse, mutect2, varscan2
- PSKH2 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs769072498, COSV52613114; called by muse, mutect2, varscan2
- PTCHD3 | c.1790C>A p.T597K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs770276918, COSV101438953, COSV71257323; called by muse, mutect2, varscan2
- PTCHD4 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV59799771; called by muse, mutect2, varscan2
- PTDSS1 | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV61266367; called by mutect2, varscan2
- PTH2R | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as rs1440563512, COSV55921138; called by muse, mutect2, varscan2
- PTPRD | c.947A>G p.Q316R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100645394, COSV61987902; called by muse, mutect2
- PTPRJ | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV69252041, COSV69255061; called by muse, mutect2, varscan2
- PTPRT | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV62030255; called by muse, mutect2, varscan2
- PYDC2 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV72921512; called by muse, mutect2, varscan2
- PZP | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54358815, COSV54369584; called by muse, mutect2, varscan2
- RABGGTA | c.1223T>C p.F408S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52865974; called by muse, mutect2
- RAG1 | c.2340A>T p.K780N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55029083; called by muse, mutect2, varscan2
- RAPGEF2 | c.1563A>T p.K521N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV52434689; called by muse, mutect2, varscan2
- RBM12B | c.2043G>T p.E681D | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1426620830, COSV67899096; called by muse, mutect2, varscan2
- RDM1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as rs1469769541; called by muse, mutect2, varscan2
- RECK | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65036572; called by muse, mutect2, varscan2
- RELN | c.4862A>G p.Y1621C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59038913; called by muse, mutect2, varscan2
- REM1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV99148131; called by muse, mutect2, varscan2
- REM1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as COSV99148142; called by muse, mutect2, varscan2
- REP15 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV57299947; called by muse, mutect2, varscan2
- REPIN1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68293107; called by muse, mutect2, varscan2
- RET | c.1451T>C p.M484T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs763617146, COSV60710776; called by muse, mutect2, varscan2
- RGS18 | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs112220830, COSV66510358; called by muse, mutect2, varscan2
- RGS4 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV63358589; called by muse, mutect2, varscan2
- RGS7 | c.1129G>C p.V377L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV58564022; called by muse, varscan2
- RIMS2 | c.1585G>A p.D529N (on ENST00000666250 / NM_001348490.2; = p.D337N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV51731982; called by muse, mutect2, varscan2
- RIMS2 | c.4034G>T p.S1345I | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51666279; called by muse, mutect2, varscan2
- RNASE4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as rs1218917599, COSV59012833; called by muse, mutect2, varscan2
- RNF213 | c.6025A>G p.M2009V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1229694474, COSV60410901; called by muse, mutect2, varscan2
- RNPS1 | c.72-1G>T p.X24_splice | Splice Site (SNP) | VAF 39/83 reads (47%) | catalogued as rs112148202, COSV57048305; called by muse, mutect2, varscan2
- RPL22L1 | c.9G>T p.P3= | Splice Region (SNP) | VAF 12/80 reads (15%) | catalogued as rs985181044, COSV55557481, COSV99860582; called by muse, mutect2, varscan2
- RPL26L1 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV54199415, COSV54200471; called by muse, mutect2, varscan2
- RSPO1 | c.17G>T p.C6F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62975596; called by muse, mutect2, varscan2
- RTL4 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61206569, COSV61207484; called by muse, mutect2, varscan2
- RTTN | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs780751185, COSV55353802; called by muse, mutect2, varscan2
- RYR2 | c.7087T>A p.S2363T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV63720133; called by muse, mutect2
- RYR2 | c.8618C>A p.P2873H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63720136; called by muse, mutect2, varscan2
- RYR2 | c.9749G>T p.W3250L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV63720144; called by muse, mutect2, varscan2
- RYR3 | c.4291C>A p.L1431M | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.372); catalogued as COSV66811082; called by muse, mutect2, varscan2
- SALL1 | c.3572C>A p.A1191E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51765538; called by muse, mutect2, varscan2
- SALL3 | c.2820C>A p.S940R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV73306720; called by muse, mutect2
- SAMD3 | c.446T>A p.L149* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV60778241; called by muse, mutect2, varscan2
- SAMD9 | c.3373C>T p.Q1125* | Nonsense Mutation (SNP) | VAF 44/139 reads (32%) | catalogued as COSV66078016; called by muse, mutect2, varscan2
- SAMD9L | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV59086060; called by muse, mutect2, varscan2
- SAP30L | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51738480; called by muse, mutect2, varscan2
- SATL1 | c.1288G>T p.D430Y (on ENST00000395409; = p.D617Y on NM_001012980.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60578492; called by muse, mutect2, varscan2
- SCML4 | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV64634294, COSV64638400; called by muse, mutect2, varscan2
- SCN11A | c.5022G>T p.M1674I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56579827; called by muse, mutect2, varscan2
- SCN2A | c.5671G>A p.V1891I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.097); catalogued as COSV51858076; called by muse, mutect2, varscan2
- SCN3A | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV51827373; called by muse, varscan2
- SCYL2 | c.1832A>T p.E611V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62571091; called by muse, mutect2, varscan2
- SDR42E1 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61095228; called by muse, mutect2, varscan2
- SEC22A | c.148A>T p.R50* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV59374212; called by muse, mutect2, varscan2
- SEMA5A | c.2264G>T p.C755F | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66807374; called by muse, mutect2, varscan2
- SEPTIN9 | c.52A>T p.R18W | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV70729421; called by muse, mutect2, varscan2
- SERPINA11 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58242172, COSV58243573; called by muse, mutect2, varscan2
- SERPINB12 | c.674C>A p.T225K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54032923, COSV54035304; called by muse, mutect2, varscan2
- SERPINB3 | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs1240038235, COSV52194918; called by muse, mutect2, varscan2
- SESN2 | c.157-1G>T p.X53_splice | Splice Site (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53429789; called by muse, mutect2, varscan2
- SESN3 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV53587884; called by muse, mutect2, varscan2
- SEZ6L | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50697707; called by muse, mutect2, varscan2
- SEZ6L2 | c.1279G>T p.E427* (on ENST00000308713 / NM_001114099.3; = p.E357* on NM_012410.4) | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV58105108; called by muse, mutect2, varscan2
601 further variants in this file (278 protein-altering or splice-affecting, 293 silent, 30 other) are not listed here.
